Somatic mutation profile of tumor specimen TCGA-23-2084-01A (aliquot TCGA-23-2084-01A-02W-0722-08) from TCGA case TCGA-23-2084, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 45.2 years (16,493 days).
Specimen TCGA-23-2084-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3acef370-d994-4e46-af6f-be1f29ba1710.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-23-2084-10A (Blood Derived Normal), aliquot TCGA-23-2084-10A-01W-0722-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/597a05e4-6531-4b7c-ab1e-9749da9235ef

The open-access MAF lists 144 somatic variants for this specimen: 109 protein-altering or splice-affecting, 30 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 94, Silent 30, Splice Site 5, Frame Shift Del 4, Nonsense Mutation 3, In Frame Del 2, Intron 2, RNA 1, 3'Flank 1, Translation Start Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.461G>T p.G154V | Missense Mutation (SNP) | VAF 79/119 reads (66%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs762846821, CM951223, COSV52667239, COSV52783646, COSV53625267; called by muse, mutect2, varscan2
- ABCD2 | c.421C>T p.R141W | Missense Mutation (SNP) | VAF 58/109 reads (53%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.832); catalogued as rs776317283, COSV100429137; called by muse, mutect2, varscan2
- AFF2 | c.743C>T p.A248V | Missense Mutation (SNP) | VAF 61/308 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as rs782374220, COSV60675733; called by muse, mutect2, varscan2
- AGAP6 | c.1483T>C p.S495P (on ENST00000374056 / NM_001365867.1; = p.S518P on NM_001077665.2) | Missense Mutation (SNP) | VAF 91/314 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100929037; called by muse, mutect2, varscan2
- AHCYL1 | c.685G>T p.D229Y | Missense Mutation (SNP) | VAF 79/284 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100779377; called by muse, mutect2, varscan2
- ATP4A | c.296A>T p.E99V | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV99382098; called by muse, mutect2, varscan2
- BRWD3 | c.3442G>A p.E1148K | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); catalogued as COSV100955638, COSV64745021; called by muse, mutect2, varscan2
- CAPN3 | c.1634A>T p.Q545L | Missense Mutation (SNP) | VAF 80/136 reads (59%) | SIFT tolerated (0.07); PolyPhen benign (0.201); catalogued as COSV100520331; called by muse, mutect2, varscan2
- CCDC105 | c.961G>A p.V321I | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.85); PolyPhen benign (0.003); catalogued as COSV99479727; called by muse, mutect2, varscan2
- CELA3B | c.670C>T p.P224S | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.07); catalogued as COSV100448585; called by muse, mutect2, varscan2
- CLOCK | c.438+2del p.X146_splice | Splice Site (DEL) | VAF 9/15 reads (60%) | catalogued as COSV59403510; called by mutect2, pindel, varscan2
- CNOT2 | c.1546C>G p.L516V | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.888); catalogued as COSV99972329; called by muse, mutect2, varscan2
- COL11A2 | c.3259-2A>G p.X1087_splice (on ENST00000341947 / NM_080680.3; = p.X980_splice on NM_080679.2) | Splice Site (SNP) | VAF 12/33 reads (36%) | catalogued as COSV100553406; called by muse, mutect2, varscan2
- CSMD3 | c.4485T>A p.H1495Q (on ENST00000297405 / NM_001363185.1; = p.H1391Q on NM_052900.3) | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); catalogued as COSV99824127; called by muse, mutect2, varscan2
- DAPK1 | c.2791C>A p.L931M | Missense Mutation (SNP) | VAF 38/136 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0.037); catalogued as COSV100800949; called by muse, varscan2
- DCAF1 | c.2909G>A p.R970K | Missense Mutation (SNP) | VAF 56/329 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100244079; called by muse, mutect2, varscan2
- DCAF8L1 | c.357G>A p.M119I | Missense Mutation (SNP) | VAF 115/184 reads (63%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as COSV101491379; called by muse, mutect2, varscan2
- DDHD1 | c.270G>A p.M90I (on ENST00000323669; = p.M321I on NM_030637.3) | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV100079020; called by muse, mutect2, varscan2
- DDX56 | c.1110C>G p.I370M | Missense Mutation (SNP) | VAF 20/31 reads (65%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.563); catalogued as COSV51835633, COSV99345908; called by muse, mutect2, varscan2
- DOCK4 | c.1310C>A p.T437N | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as COSV101455440; called by muse, mutect2, varscan2
- ELOA | c.1046A>G p.N349S | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.073); catalogued as COSV101403597; called by mutect2, varscan2
- ENPP6 | c.170G>T p.G57V | Missense Mutation (SNP) | VAF 16/157 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99698451; called by muse, mutect2, varscan2
- ERCC4 | c.458G>T p.R153L | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121913050, CM067665, COSV100318638, COSV61312767; called by muse, mutect2, varscan2
- ERG | c.111G>C p.K37N | Missense Mutation (SNP) | VAF 13/152 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV99901148; called by muse, mutect2
- FAM160A2 | c.809C>A p.S270* | Nonsense Mutation (SNP) | VAF 371/662 reads (56%) | catalogued as COSV99791698; called by muse, mutect2, varscan2
- FMN1 | c.3747G>C p.L1249F (on ENST00000616417 / NM_001277313.2; = p.L1026F on NM_001103184.4) | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754118314, COSV100567943; called by muse, mutect2
- FMO4 | c.1573G>T p.A525S | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.026); catalogued as rs775513653, COSV63001695; called by muse, mutect2, varscan2
- FNBP1 | c.1621G>A p.D541N | Missense Mutation (SNP) | VAF 73/202 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.251); catalogued as rs370514877; called by muse, mutect2, varscan2
- FRMPD4 | c.305G>C p.R102P | Missense Mutation (SNP) | VAF 38/201 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV101042110, COSV66212776; called by muse, mutect2, varscan2
- FRS2 | c.616C>T p.R206W | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.249); catalogued as rs769491241, COSV54724649; called by muse, mutect2, varscan2
- GBP2 | c.832A>C p.K278Q | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100975330; called by muse, mutect2
- GTF2F2 | c.527C>T p.A176V | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.54); PolyPhen benign (0.015); catalogued as COSV100476501; called by muse, varscan2
- GTF2H2 | c.751C>T p.R251C | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV99174111; called by mutect2, varscan2
- HIPK2 | c.651G>T p.W217C | Missense Mutation (SNP) | VAF 143/262 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100702020; called by muse, mutect2, varscan2
- HIPK3 | c.2740C>T p.P914S | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.581); catalogued as COSV100305362, COSV100306066; called by muse, mutect2, varscan2
- HOXC8 | c.458G>T p.R153L | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50000970, COSV99236630; called by muse, mutect2
- HSPA6 | c.1605G>T p.R535S | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.633); catalogued as COSV100553860; called by muse, mutect2, varscan2
- IKZF3 | c.1220T>C p.V407A | Missense Mutation (SNP) | VAF 68/241 reads (28%) | SIFT tolerated (0.72); PolyPhen benign (0.006); catalogued as rs1018574162, COSV99499205; called by muse, varscan2
- KCNK3 | c.608G>T p.G203V | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM136950, COSV100256629, COSV57192001; called by muse, mutect2, varscan2
- KCNK9 | c.400A>C p.T134P | Missense Mutation (SNP) | VAF 59/157 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.464); catalogued as COSV100270264; called by muse, mutect2, varscan2
- KCNS2 | c.1154C>T p.T385M | Missense Mutation (SNP) | VAF 67/162 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.257); catalogued as rs201873843, COSV54637904; called by muse, mutect2, varscan2
- KIFC1 | c.1811T>A p.M604K | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.747); catalogued as COSV100995971; called by muse, mutect2
- KIFC1 | c.1812G>T p.M604I | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.681); catalogued as COSV100995973; called by muse, mutect2
- KLRF1 | c.292A>G p.S98G | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT tolerated (0.51); PolyPhen benign (0.012); catalogued as rs757670768, COSV99684279; called by muse, mutect2, varscan2
- KRT6A | c.1317G>T p.Q439H | Missense Mutation (SNP) | VAF 76/455 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100416678; called by muse, mutect2, varscan2
- L1TD1 | c.1733G>T p.S578I | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV100776533; called by muse, mutect2, varscan2
- LMTK2 | c.3937G>A p.E1313K | Missense Mutation (SNP) | VAF 26/326 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.492); catalogued as rs1012203765, COSV99805967; called by muse, mutect2
- LRP12 | c.1793G>A p.R598K | Missense Mutation (SNP) | VAF 14/204 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as COSV52627734; called by muse, mutect2
- LY75 | c.689A>T p.Y230F | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99715934; called by muse, mutect2, varscan2
- MID2 | c.721C>G p.Q241E | Missense Mutation (SNP) | VAF 145/203 reads (71%) | SIFT tolerated (0.52); PolyPhen benign (0.014); catalogued as COSV99463971; called by muse, mutect2, varscan2
- MTMR12 | c.2236G>A p.D746N | Missense Mutation (SNP) | VAF 41/186 reads (22%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.014); catalogued as COSV99373346; called by muse, mutect2
- MUC16 | c.29428T>A p.S9810T | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as COSV101198067; called by muse, mutect2, varscan2
- MUC16 | c.8831C>T p.S2944F | Missense Mutation (SNP) | VAF 123/249 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.919); catalogued as COSV67458880; called by muse, mutect2, varscan2
- MUC5B | c.12937A>G p.S4313G | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV101500021; called by muse, mutect2, varscan2
- NCOA6 | c.276C>A p.N92K | Missense Mutation (SNP) | VAF 21/166 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV100749902; called by muse, mutect2, varscan2
- NCOR1 | c.4982C>T p.T1661I | Missense Mutation (SNP) | VAF 143/216 reads (66%) | SIFT tolerated (0.43); PolyPhen benign (0.12); catalogued as COSV99247032; called by muse, mutect2, varscan2
- NNT | c.3244G>T p.E1082* | Nonsense Mutation (SNP) | VAF 28/133 reads (21%) | catalogued as rs1353857489, COSV99238371; called by muse, mutect2, varscan2
- NRDC | c.1866T>G p.H622Q | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.306); catalogued as COSV100703058; called by muse, mutect2, varscan2
- OCA2 | c.910A>G p.I304V | Missense Mutation (SNP) | VAF 243/264 reads (92%) | SIFT tolerated (0.51); PolyPhen benign (0.015); catalogued as rs758386323, COSV100666939; called by muse, mutect2, varscan2
- OR2F1 | c.269A>C p.K90T | Missense Mutation (SNP) | VAF 147/719 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101231284; called by muse, mutect2, varscan2
- OR4D9 | c.436G>T p.V146L | Missense Mutation (SNP) | VAF 76/186 reads (41%) | SIFT tolerated (0.24); PolyPhen benign (0.034); catalogued as COSV100259696, COSV61434635; called by muse, mutect2, varscan2
- PAF1 | c.1379C>A p.S460Y | Missense Mutation (SNP) | VAF 44/365 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.462); catalogued as COSV99655582; called by muse, mutect2, varscan2
- PCDH15 | c.4802G>T p.G1601V (on ENST00000644397 / NM_001354429.2; = p.G1543V on NM_001142771.2) | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100902936, COSV64732270; called by muse, mutect2, varscan2
- PCIF1 | c.1137C>G p.H379Q | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100532606; called by muse, varscan2
- PDCD11 | c.3517G>T p.D1173Y | Missense Mutation (SNP) | VAF 23/256 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.825); catalogued as COSV100874232; called by muse, mutect2
- PEAR1 | c.2996C>A p.P999H | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99440566; called by muse, mutect2, varscan2
- PLEKHG1 | c.1867G>C p.G623R | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100651451; called by mutect2, varscan2
- POU3F4 | c.288C>A p.H96Q | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.063); catalogued as COSV100937158; called by muse, mutect2, varscan2
- PPARA | c.1068A>C p.E356D | Missense Mutation (SNP) | VAF 43/84 reads (51%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.998); catalogued as COSV99415122; called by muse, mutect2, varscan2
- PRDM16 | c.2940-1G>C p.X980_splice | Splice Site (SNP) | VAF 10/68 reads (15%) | catalogued as COSV99575414; called by muse, mutect2
- PRKCZ | c.763A>T p.I255F | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.248); catalogued as COSV101057436; called by muse, mutect2
- PXDNL | c.1007C>T p.P336L | Missense Mutation (SNP) | VAF 89/264 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs865988145, COSV100681192; called by muse, mutect2, varscan2
- ROBO3 | c.3084G>C p.E1028D | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.031); catalogued as COSV101184898; called by muse, varscan2
- SCN2A | c.1729C>T p.L577F | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.606); catalogued as rs796053187, COSV51855359; called by muse, mutect2, varscan2
- SEPHS2 | c.736G>T p.D246Y | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV101529301; called by muse, mutect2, varscan2
- SH3TC2 | c.2089G>T p.G697C | Missense Mutation (SNP) | VAF 23/210 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.864); catalogued as COSV100101155; called by muse, mutect2, varscan2
- SLC16A12 | c.605C>G p.S202C | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100369994, COSV57950826; called by muse, mutect2, varscan2
- SLC28A3 | c.874G>A p.V292M | Missense Mutation (SNP) | VAF 281/676 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); catalogued as rs202155610, COSV100883142; called by muse, varscan2
- SLC5A11 | c.1838A>G p.K613R | Missense Mutation (SNP) | VAF 38/168 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV100762659; called by muse, mutect2, varscan2
- SLC6A17 | c.1249T>C p.F417L | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.06); catalogued as COSV100521079; called by muse, mutect2, varscan2
- SMARCA2 | c.1840G>T p.A614S | Missense Mutation (SNP) | VAF 9/152 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.033); catalogued as COSV100570255; called by muse, mutect2
- STIM1 | c.1475-2A>C p.X492_splice | Splice Site (SNP) | VAF 12/31 reads (39%) | catalogued as COSV100330510; called by muse, mutect2, varscan2
- STIM1 | c.1475-1G>T p.X492_splice | Splice Site (SNP) | VAF 14/34 reads (41%) | catalogued as COSV100330511; called by muse, mutect2
- SYNE3 | c.2435A>T p.N812I | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.278); catalogued as COSV100515629; called by muse, mutect2, varscan2
- TAS2R31 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 48/64 reads (75%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.918); catalogued as rs562236488, COSV101114065; called by muse, varscan2
- TDRKH | c.867G>C p.E289D | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.437); catalogued as COSV100917864; called by muse, mutect2, varscan2
- TFRC | c.106G>A p.V36M | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100786388; called by muse, mutect2, varscan2
- TLE4 | c.1493C>G p.P498R | Missense Mutation (SNP) | VAF 87/391 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV54627611, COSV99511118; called by muse, mutect2, varscan2
- TPH2 | c.1141C>A p.L381I | Missense Mutation (SNP) | VAF 72/170 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as COSV100421880; called by muse, mutect2, varscan2
- TRARG1 | c.517A>T p.T173S | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV100416722; called by muse, mutect2, varscan2
- TRARG1 | c.518C>T p.T173I | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as rs533341843, COSV100416724; called by muse, mutect2, varscan2
- TRIM22 | c.423G>C p.Q141H | Missense Mutation (SNP) | VAF 49/339 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); catalogued as COSV101181194; called by muse, mutect2, varscan2
- TTN | c.33055C>T p.R11019C (on ENST00000591111; = p.R10092C on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/64 reads (16%) | PolyPhen benign (0.172); catalogued as rs763380355, COSV59956834; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UBA7 | c.1451G>T p.R484M | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100339587; called by muse, mutect2, varscan2
- VSNL1 | c.97G>C p.G33R | Missense Mutation (SNP) | VAF 63/333 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV54600030, COSV99722830; called by muse, mutect2, varscan2
- WDR45 | c.1053C>G p.Y351* (on ENST00000376372 / NM_001029896.2; = p.Y352* on NM_007075.3) | Nonsense Mutation (SNP) | VAF 23/77 reads (30%) | catalogued as CM1514394, COSV100540075; called by muse, mutect2, varscan2
- WDR88 | c.496G>T p.D166Y | Missense Mutation (SNP) | VAF 87/181 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100866398, COSV63450541; called by muse, mutect2, varscan2
- ZFC3H1 | c.384T>G p.S128R | Missense Mutation (SNP) | VAF 100/602 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV100350322; called by mutect2, varscan2
- ZNF536 | c.3565A>T p.M1189L | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0); catalogued as COSV100834633; called by muse, mutect2, varscan2
- ZNF786 | c.2185G>A p.E729K | Missense Mutation (SNP) | VAF 54/238 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs752774030, COSV100302653; called by muse, mutect2, varscan2
- ZNF81 | c.1129C>A p.Q377K | Missense Mutation (SNP) | VAF 51/141 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.456); catalogued as COSV100095355; called by muse, mutect2, varscan2
- CCNF | c.869_900del p.S290Cfs*7 | Frame Shift Del (DEL) | VAF 16/88 reads (18%) | called by mutect2, pindel
- CDKN1A | c.23_55del p.V8_R19delinsG | In Frame Del (DEL) | VAF 5/30 reads (17%) | called by mutect2, pindel
- OSR2 | c.62_68del p.Y21Sfs*5 | Frame Shift Del (DEL) | VAF 41/88 reads (47%) | called by mutect2, pindel, varscan2
- PI15 | c.351_362del p.L118_L121del | In Frame Del (DEL) | VAF 68/260 reads (26%) | called by pindel, varscan2
- PRAMEF4 | c.779C>A p.T260N | Missense Mutation (SNP) | VAF 26/846 reads (3%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.636); called by muse, mutect2
- SEPTIN12 | c.477C>G p.H159Q | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- SYNE2 | c.8352_8359delinsA p.L2785Kfs*18 | Frame Shift Del (DEL) | VAF 21/190 reads (11%) | called by pindel, varscan2*
- ZBTB40 | c.2316_2336delinsG p.S772Rfs*32 | Frame Shift Del (DEL) | VAF 49/88 reads (56%) | called by pindel, varscan2*
- ACOX1 | c.1194G>C p.G398= | Silent (SNP) | VAF 66/143 reads (46%) | catalogued as COSV99503266; called by muse, mutect2, varscan2
- ALMS1 | c.5556A>T p.P1852= | Silent (SNP) | VAF 11/91 reads (12%) | catalogued as COSV100041078; called by muse, mutect2, varscan2
- BEND6 | c.270A>T p.R90= | Silent (SNP) | VAF 20/120 reads (17%) | catalogued as COSV100876746; called by muse, mutect2, varscan2
- CACNA2D2 | c.927G>C p.L309= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV99816793; called by mutect2, varscan2
- CAPRIN2 | c.318T>G p.S106= | Silent (SNP) | VAF 28/190 reads (15%) | catalogued as COSV99195411; called by muse, varscan2
- CKMT2 | c.633C>T p.S211= | Silent (SNP) | VAF 18/75 reads (24%) | catalogued as rs140162798; called by muse, mutect2, varscan2
- CLVS2 | c.108T>C p.D36= | Silent (SNP) | VAF 48/73 reads (66%) | catalogued as rs1200040807, COSV99252118; called by muse, mutect2, varscan2
- CPS1 | c.4047A>C p.A1349= | Silent (SNP) | VAF 41/128 reads (32%) | catalogued as COSV99242113; called by muse, mutect2, varscan2
- F13A1 | c.1692C>G p.V564= | Silent (SNP) | VAF 45/386 reads (12%) | catalogued as COSV99342135; called by muse, mutect2, varscan2
- FCGBP | c.10959C>T p.G3653= | Silent (SNP) | VAF 11/49 reads (22%) | called by muse, mutect2, varscan2
- FSIP2 | c.20199C>A p.I6733= | Silent (SNP) | VAF 34/212 reads (16%) | catalogued as COSV100553932; called by muse, mutect2, varscan2
- HEG1 | c.3333C>A p.I1111= | Silent (SNP) | VAF 23/186 reads (12%) | catalogued as COSV100230027; called by muse, mutect2, varscan2
- IDE | c.1569A>G p.K523= | Silent (SNP) | VAF 24/40 reads (60%) | catalogued as COSV99793762; called by muse, mutect2, varscan2
- KCNQ3 | c.2373C>T p.S791= | Silent (SNP) | VAF 15/288 reads (5%) | catalogued as rs1223970817, COSV101195479; called by muse, mutect2
- KCTD19 | c.2508G>A p.R836= | Silent (SNP) | VAF 12/19 reads (63%) | catalogued as COSV100430642; called by mutect2, varscan2
- KIF1B | c.1704C>T p.D568= (on ENST00000377086 / NM_001365952.1; = p.D522= on NM_015074.3) | Silent (SNP) | VAF 114/325 reads (35%) | catalogued as COSV99822402; called by muse, mutect2, varscan2
- M1AP | c.1155T>C p.Y385= | Silent (SNP) | VAF 59/393 reads (15%) | catalogued as rs767262447, COSV99283915; called by muse, mutect2, varscan2
- MCRS1 | c.901C>T p.L301= | Silent (SNP) | VAF 10/81 reads (12%) | catalogued as rs745814149, COSV99234695; called by muse, mutect2, varscan2
- MMP20 | c.978C>T p.H326= | Silent (SNP) | VAF 44/91 reads (48%) | catalogued as COSV99497375; called by muse, varscan2
- MRPL36 | c.261G>A p.R87= | Silent (SNP) | VAF 18/35 reads (51%) | catalogued as rs1427257278, COSV99928889; called by muse, mutect2, varscan2
- NKAP | c.99T>G p.S33= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as COSV101004172; called by muse, mutect2
- PCDHA7 | c.2109C>T p.A703= | Silent (SNP) | VAF 45/170 reads (26%) | catalogued as rs782031077, COSV65337235; called by muse, mutect2, varscan2
- PCDHB7 | c.2118C>T p.F706= | Silent (SNP) | VAF 18/132 reads (14%) | catalogued as rs868962799, COSV50753682; called by muse, mutect2, varscan2
- PHKG2 | c.543C>T p.G181= | Silent (SNP) | VAF 79/136 reads (58%) | catalogued as rs372239376; called by muse, varscan2
- RFT1 | c.1591T>C p.L531= | Silent (SNP) | VAF 18/82 reads (22%) | called by mutect2, varscan2
- RIC1 | c.2040C>A p.I680= | Silent (SNP) | VAF 137/451 reads (30%) | catalogued as COSV52615675, COSV99316623; called by muse, mutect2, varscan2
- SHH | c.438G>T p.V146= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV99793257; called by mutect2, varscan2
- SLC5A11 | c.474C>A p.I158= | Silent (SNP) | VAF 47/106 reads (44%) | catalogued as rs1397959526, COSV100762658; called by muse, mutect2, varscan2
- ZAN | c.4722C>A p.S1574= | Silent (SNP) | VAF 29/87 reads (33%) | catalogued as COSV100769103; called by muse, mutect2, varscan2
- ZHX3 | c.1230T>A p.L410= | Silent (SNP) | VAF 14/323 reads (4%) | catalogued as COSV100475434; called by muse, mutect2
- COMMD9 | chr11:36271743 G>A | 3'Flank (SNP) | VAF 22/115 reads (19%) | called by mutect2, varscan2
- MIR1207 | n.68T>A | RNA (SNP) | VAF 21/183 reads (11%) | called by muse, mutect2, varscan2
- MMP16 | c.1222+5161A>T | Intron (SNP) | VAF 30/75 reads (40%) | catalogued as rs776357219, COSV99685933; called by muse, varscan2
- NRG1 | c.502+31075C>A | Intron (SNP) | VAF 91/226 reads (40%) | catalogued as COSV99827563; called by muse, mutect2, varscan2
- ZNF493 | c.-110A>T | 5'UTR (SNP) | VAF 6/22 reads (27%) | catalogued as COSV100828555; called by muse, mutect2, varscan2
